Somatic mutation profile of tumor specimen MMRF_2228_1_BM_CD138pos (aliquot MMRF_2228_1_BM_CD138pos_T2_KHS5U_K14053) from MMRF case MMRF_2228, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.2 years (22,361 days).
Specimen MMRF_2228_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa5aa117-3482-4641-b312-c1e7da16d156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2228_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2228_1_PB_Whole_C1_KHS5U_K14052; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f7c8a71-222f-4fba-aa60-5feddb6070e5

The open-access MAF lists 78 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 21, Silent 8, Intron 4, 5'UTR 3, 3'Flank 2, RNA 2, 5'Flank 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACA | c.2636C>T p.T879M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as rs764378176; called by muse, mutect2, varscan2
- CDKN1B | c.222C>G p.Y74* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | catalogued as COSV57430528; called by muse, mutect2
- CHRM1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1258843299; called by muse, mutect2, varscan2
- DOCK1 | c.4844G>A p.R1615Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as rs748312033, COSV54737112; called by mutect2, varscan2
- GALR2 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); catalogued as COSV57162810; called by muse, mutect2
- IGHV2-70 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.211); catalogued as rs377540429; called by muse, varscan2
- IGLV3-1 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs61731694; called by muse, varscan2
- IGLV3-1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as rs61731687; called by muse, varscan2
- MAT1A | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1431988792, COSV64744520; called by muse, mutect2
- MUC3A | c.7355T>G p.V2452G | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT tolerated, low confidence (0.07); catalogued as rs796301755, COSV60222167; called by muse, mutect2, varscan2
- NUMBL | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs772850434; called by muse, mutect2, varscan2
- ORM1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 134/1210 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs767328077, COSV52281593; called by muse, varscan2
- PCDH15 | c.1322T>C p.L441P | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.962); catalogued as rs1408205242; called by muse, mutect2, varscan2
- SALL3 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs906293497, COSV73305790; called by muse, mutect2, varscan2
- SLC39A12 | c.2008T>G p.F670V (on ENST00000377369 / NM_001145195.2; = p.F633V on NM_152725.3) | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV101070175, COSV101070189; called by muse, mutect2, varscan2
- SPATA31E1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs764330261; called by muse, mutect2, varscan2
- TAB1 | c.656C>G p.S219W | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53373523; called by muse, mutect2
- ZMYM3 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs771809730; called by muse, mutect2, varscan2
- ZNF71 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60146414; called by muse, mutect2, varscan2
- B2M | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, varscan2
- BRWD1 | c.149A>T p.K50M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CELF1 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX53 | c.1589G>A p.G530D | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DISP1 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.491); called by muse, mutect2
- FIP1L1 | c.964_967del p.T322Sfs*4 | Frame Shift Del (DEL) | VAF 16/204 reads (8%) | called by mutect2, pindel
- HELLS | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IGHV2-70D | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.94); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LEPR | c.372T>G p.D124E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- METTL25 | c.601T>G p.Y201D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NCAM2 | c.1891A>T p.R631* | Nonsense Mutation (SNP) | VAF 13/191 reads (7%) | called by muse, mutect2
- RPL10L | c.363A>T p.K121N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- SDCBP | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- SMARCD1 | c.531G>A p.K177= | Splice Region (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- SUPT20HL1 | c.2354G>A p.R785K | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.567); called by muse, mutect2
- TENT5C | c.535T>A p.F179I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UNC80 | c.5669T>G p.L1890R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRF5 | c.2277G>A p.A759= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs149269256; called by muse, mutect2, varscan2
- CASD1 | c.2050C>T p.L684= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- COL25A1 | c.1677A>G p.G559= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as rs1288702129; called by muse, mutect2, varscan2
- CXCR4 | c.324A>G p.L108= | Silent (SNP) | VAF 87/172 reads (51%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.345G>A p.Q115= | Silent (SNP) | VAF 59/69 reads (86%) | catalogued as rs375238504; called by muse, mutect2, varscan2
- PHRF1 | c.2556C>T p.P852= (on ENST00000264555 / NM_001286581.2; = p.P851= on NM_020901.4) | Silent (SNP) | VAF 32/306 reads (10%) | catalogued as rs763023941, COSV52760403; called by muse, mutect2, varscan2
- PLOD3 | c.558G>A p.K186= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as rs1261766826; called by muse, mutect2, varscan2
- WASL | c.1488T>C p.D496= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- ADGRF1 | c.611+730C>T | Intron (SNP) | VAF 72/184 reads (39%) | catalogued as rs1218726878; called by muse, mutect2, varscan2
- ALG6 | c.*1211A>C | 3'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498058 G>C | 5'Flank (SNP) | VAF 86/217 reads (40%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*3131G>A | 3'UTR (SNP) | VAF 15/83 reads (18%) | catalogued as COSV50843264; called by muse, mutect2, varscan2
- BSPRY | c.*253C>T | 3'UTR (SNP) | VAF 28/40 reads (70%) | called by muse, mutect2, varscan2
- CCDC162P | n.1988A>G | RNA (SNP) | VAF 14/48 reads (29%) | catalogued as rs1013713596; called by muse, varscan2
- CDH1 | c.-102A>T | 5'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- CFTRP2 | n.57T>G | RNA (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2
- CHMP7 | c.-161_-143del | 5'UTR (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- COG5 | c.*110A>C | 3'UTR (SNP) | VAF 33/247 reads (13%) | called by muse, mutect2, varscan2
- CYP4F12 | c.525+14A>C | Intron (SNP) | VAF 26/241 reads (11%) | called by muse, mutect2, varscan2
- DCDC2 | c.*6T>G | 3'UTR (SNP) | VAF 73/202 reads (36%) | catalogued as COSV101015347; called by muse, mutect2
- FAM221B | c.*6G>C | 3'UTR (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- GRIN2A | c.*6114G>T | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863439 T>G | 5'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as rs141217017; called by muse, varscan2
- KCNH5 | c.*795A>G | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- KMT5C | c.-47C>T | 5'UTR (SNP) | VAF 79/197 reads (40%) | called by muse, mutect2, varscan2
- KRCC1 | c.*126T>G | 3'UTR (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- MLLT3 | c.*616T>A | 3'UTR (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- OSBPL1A | c.*602G>A | 3'UTR (SNP) | VAF 24/91 reads (26%) | called by muse, varscan2
- PANK2 | chr20:3925082 C>G | 3'Flank (SNP) | VAF 133/265 reads (50%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.*457G>A | 3'UTR (SNP) | VAF 22/78 reads (28%) | called by muse, varscan2
- QRFPR | c.562-1529G>T | Intron (SNP) | VAF 53/156 reads (34%) | catalogued as rs1377415283; called by muse, mutect2, varscan2
- RAB29 | chr1:205768187 T>C | 3'Flank (SNP) | VAF 23/50 reads (46%) | catalogued as rs1419289540; called by muse, mutect2, varscan2
- SIK2 | c.*924A>G | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- SLFNL1 | c.-118-153C>A | Intron (SNP) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- SLIT2 | c.*1194T>G | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- TLCD5 | c.*2823T>C | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- TNRC18 | c.*87T>G | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2
- TP53INP2 | c.*2499A>G | 3'UTR (SNP) | VAF 23/116 reads (20%) | catalogued as rs1239874082; called by muse, mutect2, varscan2
- TRPV3 | c.*3118C>T | 3'UTR (SNP) | VAF 5/102 reads (5%) | catalogued as rs935066516; called by muse, mutect2
- TXLNA | c.*1464A>G | 3'UTR (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- ZFP82 | c.*529G>T | 3'UTR (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- ZNF420 | c.*644A>G | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
